FM case AD3905 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/3920d077-2773-45d9-b09a-cb687a0e7522

Female, 53.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the thymus; primary biopsied or resected from the thymus. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
